Gene-level copy-number profile of tumor specimen ALCH-AF49-TTP1-A from ALCHEMIST case ALCH-AF49, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 51.6 years (18,837 days).
Specimen ALCH-AF49-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c4a036f0-f23e-44de-a3a3-edc6f0e9a20b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AF49-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/4665434e-c083-4985-9b8c-9499a63545e3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 102; copy number 1: 1,396; copy number 2: 56,305; copy number 3: 555; copy number 4: 36; copy number 7: 1; copy number 9: 1; copy number 41: 2.

Homozygous deletions (total copy number 0; autosomes only): 101 genes in 37 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,124,337–16,161,883, 3 genes: EPHA2, AL451042.2, AL451042.1.
- chr1:16,974,502–16,980,632, 2 genes (within-gene range 0–2): MFAP2, AL049569.2.
- chr1:19,682,213–19,799,945, 1 gene: TMCO4.
- chr1:20,692,734–20,732,837, 2 genes (within-gene range 0–2): AL663074.2, SH2D5.
- chr1:39,757,182–39,788,865, 3 genes (within-gene range 0–2): BMP8B, OXCT2, BMP8B-AS1.
- chr2:108,894,471–108,989,372, 1 gene: EDAR.
- chr2:131,464,900–131,521,573, 4 genes: MZT2A, TUBA3D, MIR4784, SMPD4BP.
- chr3:47,818,005–47,818,128, 1 gene (within-gene range 0–2): AC026318.1.
- chr3:52,316,319–52,400,491, 2 genes: DNAH1, PPP2R5CP.
- chr3:183,806,457–183,810,783, 1 gene (within-gene range 0–2): YEATS2-AS1.
- chr5:441,498–443,160, 1 gene (within-gene range 0–1): EXOC3-AS1.
- chr5:473,236–480,884, 1 gene (within-gene range 0–2): SLC9A3-AS1.
- chr5:150,357,629–150,400,308, 1 gene: TCOF1.
- chr5:176,707,356–176,726,243, 1 gene: AC113391.1.
- chr6:35,781,019–35,793,675, 1 gene: CLPSL1.
- chr7:98,211,439–98,252,232, 2 genes: BHLHA15, TECPR1.
- chr7:149,714,781–149,734,575, 1 gene: KRBA1.
- chr8:6,924,697–6,926,076, 1 gene: DEFA6.
- chr9:93,951,627–93,955,355, 1 gene: BARX1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:126,613,928–126,701,032, 2 genes (within-gene range 0–2): LMX1B, AL161908.2.
- chr11:47,437,764–47,449,143, 1 gene: RAPSN.
- chr12:57,229,498–57,251,188, 4 genes (within-gene range 0–2): AC137834.2, SHMT2, NDUFA4L2, STAC3.
- chr13:112,313,467–112,321,758, 1 gene: LINC01043.
- chr15:25,169,337–25,238,067, 38 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37.
- chr15:40,250,664–40,307,935, 6 genes (within-gene range 0–2): C15orf56, AC020658.6, PLCB2, ANKRD63, AC020658.5, PLCB2-AS1.
- chr15:67,819,704–67,834,582, 1 gene (within-gene range 0–2): SKOR1.
- chr15:67,834,310–67,840,045, 2 genes (within-gene range 0–2): AC009292.1, RNU6-1.
- chr15:99,416,584–99,435,160, 2 genes: AC015660.3, AC015660.1.
- chr16:50,292,616–50,292,675, 1 gene (within-gene range 0–2): MIR6771.
- chr16:56,300,616–56,353,524, 3 genes (within-gene range 0–2): AC009102.1, AC009102.3, AC009102.2.
- chr16:58,496,908–58,497,014, 1 gene (within-gene range 0–2): RNU6-103P.
- chr17:76,090,308–76,091,669, 1 gene (within-gene range 0–2): AC018665.1.
- chr19:22,596,257–22,608,501, 4 genes: GOLGA2P9, RN7SL860P, AC011467.3, AC011467.4.
- chr19:33,621,953–33,773,509, 1 gene: CHST8.
- chr19:38,184,376–38,186,265, 1 gene (within-gene range 0–2): AC011479.3.
- chr22:18,951,934–18,959,512, 1 gene: AC007326.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:3,473,986–3,480,525, 1 gene, copy number 9: SMIM24.
- chr21:44,172,169–44,207,399, 3 genes, copy number 7–41: AP001056.2, AP001056.1, AP001057.1.

Autosomal genes at a single copy (total copy number 1): 1,396. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
